Somatic mutation profile of tumor specimen 0DY8KM from CCDI case PBCRUZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 1.0 years (372 days).
Specimen 0DY8KM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e753a1-316b-4515-b59b-f7cb187234b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY8KL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5219aa1a-0cfe-41d0-9d6f-1751f1f41d57

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NALCN | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 264/2025 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51958793; called by muse, varscan2
- DISP2 | c.3626C>G p.P1209R | Missense Mutation (SNP) | VAF 100/540 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, varscan2
- SVIL | c.240C>T p.S80= | Silent (SNP) | VAF 272/1372 reads (20%) | catalogued as rs759902839; called by muse, varscan2
- FZD1 | c.-58G>T | 5'UTR (SNP) | VAF 59/329 reads (18%) | called by muse, varscan2
